Somatic mutation profile of tumor specimen TCGA-UZ-A9Q0-01A (aliquot TCGA-UZ-A9Q0-01A-12D-A42J-10) from TCGA case TCGA-UZ-A9Q0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-UZ-A9Q0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6780af48-3087-4ebb-9c52-7ef734889d7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9Q0-10A (Blood Derived Normal), aliquot TCGA-UZ-A9Q0-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/756bffff-78c8-483b-9d7a-dbd85873a69d

The open-access MAF lists 66 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 14, Frame Shift Del 7, Nonsense Mutation 2, In Frame Del 2, RNA 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL031777.2 | c.369T>G p.S123R | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV100587278; called by muse, mutect2, varscan2
- ARFGAP2 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100096637, COSV54065076; called by muse, mutect2, varscan2
- ASTN1 | c.2813G>C p.R938P | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100707710; called by muse, mutect2
- ATP5F1B | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV99467736; called by muse, mutect2, varscan2
- BANP | c.584G>A p.S195N (on ENST00000286122; = p.S164N on NM_017869.4) | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.063); catalogued as COSV99622378; called by muse, mutect2, varscan2
- BCL9L | c.2320A>G p.M774V | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV99420137; called by muse, mutect2, varscan2
- CCNT2 | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 117/274 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51471888; called by muse, mutect2, varscan2
- CFC1 | c.149del p.P50Rfs*12 | Frame Shift Del (DEL) | VAF 114/534 reads (21%) | catalogued as COSV99383460; called by mutect2, varscan2
- FAM110D | c.299A>G p.E100G | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV100957638; called by muse, mutect2, varscan2
- FAM131A | c.937C>A p.Q313K (on ENST00000310585; = p.Q344K on NM_144635.5) | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs868610503, COSV99659014; called by muse, mutect2, varscan2
- FPGS | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100948910; called by muse, mutect2, varscan2
- GOLGA3 | c.600G>T p.R200S | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as COSV99212847; called by muse, mutect2, varscan2
- GPHN | c.2059C>A p.P687T (on ENST00000315266 / NM_001377519.1; = p.P720T on NM_020806.5) | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100017779; called by muse, mutect2, varscan2
- HPD | c.47T>C p.F16S | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000233; called by muse, mutect2, varscan2
- IDUA | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs1170717159, COSV99926476; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV99861036; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1282A>G p.S428G (on ENST00000439118 / NM_001008949.3; = p.S436G on NM_178495.6) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.446); catalogued as COSV100742247; called by muse, mutect2, varscan2
- KRT82 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs377127392, COSV99233885; called by muse, mutect2, varscan2
- MCL1 | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.07); catalogued as COSV100329406, COSV100329764; called by muse, mutect2, varscan2
- MUC13 | c.1091G>A p.S364N | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); catalogued as COSV100222513; called by muse, mutect2, varscan2
- NCAPD3 | c.3406C>G p.L1136V | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV101594459; called by muse, mutect2, varscan2
- NR2F2 | c.326G>T p.R109M | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101241184; called by muse, mutect2, varscan2
- NTN1 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 78/126 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99432498, COSV99433885; called by muse, mutect2, varscan2
- PAK4 | c.673C>A p.H225N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100426614; called by muse, varscan2
- PAN2 | c.1246T>C p.S416P | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as COSV99228515; called by muse, mutect2, varscan2
- PLA2G4E | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV101268646; called by muse, mutect2, varscan2
- PLEKHA7 | c.2485T>C p.F829L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV100262021; called by muse, mutect2, varscan2
- POLR3C | c.107T>A p.L36Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100493118; called by muse, mutect2, varscan2
- PRKG1 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100907225; called by muse, mutect2, varscan2
- RASAL2 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as COSV100862932; called by muse, mutect2, varscan2
- RDH5 | c.537A>C p.K179N | Missense Mutation (SNP) | VAF 137/354 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141884; called by muse, mutect2, varscan2
- SCGN | c.275A>C p.E92A | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618861; called by muse, mutect2, varscan2
- SCYL2 | c.1486T>A p.C496S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV100675315; called by muse, mutect2, varscan2
- SDF2L1 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as COSV99963678; called by muse, mutect2
- SLU7 | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | catalogued as COSV99775848; called by muse, mutect2, varscan2
- SMARCA4 | c.3335T>G p.M1112R | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100759130, COSV60798810; called by muse, mutect2, varscan2
- SPINK5 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 141/305 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV99807380; called by muse, mutect2, varscan2
- STRIP2 | c.2122T>C p.Y708H | Missense Mutation (SNP) | VAF 77/132 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777688189, COSV99974175; called by muse, mutect2, varscan2
- TANGO6 | c.1376A>C p.K459T | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99937027; called by muse, mutect2, varscan2
- TDRKH | c.1290G>C p.Q430H | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100162706; called by muse, mutect2
- TGFB1 | c.29_31del p.P10del | In Frame Del (DEL) | VAF 4/37 reads (11%) | catalogued as rs779901179; called by mutect2, pindel
- UBE2O | c.750+2T>C p.X250_splice | Splice Site (SNP) | VAF 81/126 reads (64%) | catalogued as COSV100085067; called by muse, mutect2, varscan2
- VRTN | c.1121T>A p.L374Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99832491; called by muse, mutect2, varscan2
- ARID1A | c.5257del p.V1753Cfs*17 | Frame Shift Del (DEL) | VAF 48/136 reads (35%) | called by mutect2, pindel, varscan2
- GSDME | c.1227del p.K409Nfs*28 | Frame Shift Del (DEL) | VAF 69/134 reads (51%) | called by mutect2, pindel, varscan2
- MAGI1 | c.3709del p.R1237Gfs*198 | Frame Shift Del (DEL) | VAF 35/107 reads (33%) | called by mutect2, pindel, varscan2
- STXBP5L | c.2644_2647del p.M882Yfs*10 | Frame Shift Del (DEL) | VAF 27/109 reads (25%) | called by mutect2, pindel, varscan2
- USP25 | c.2307_2309del p.E769del | In Frame Del (DEL) | VAF 112/202 reads (55%) | called by mutect2, pindel, varscan2
- ZNF582 | c.1143del p.Q381Hfs*58 | Frame Shift Del (DEL) | VAF 40/99 reads (40%) | called by mutect2, pindel, varscan2
- ZSWIM8 | c.331del p.W111Gfs*36 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- ACACA | c.1836G>T p.V612= | Silent (SNP) | VAF 57/89 reads (64%) | called by muse, mutect2, varscan2
- ACTR10 | c.285A>G p.V95= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs747767626, COSV99581371; called by muse, mutect2, varscan2
- B3GNT4 | c.501A>T p.P167= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1423512277, COSV99928398; called by muse, mutect2, varscan2
- F12 | c.882G>A p.Q294= | Silent (SNP) | VAF 81/155 reads (52%) | catalogued as rs1486683301, COSV53692305, COSV99499934; called by muse, mutect2, varscan2
- FARP1 | c.456T>C p.N152= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100132200, COSV60345295; called by muse, mutect2, varscan2
- HSD17B8 | c.519G>A p.K173= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs1490886787, COSV100761868; called by muse, mutect2, varscan2
- HTR3D | c.1107C>T p.G369= (on ENST00000382489 / NM_001163646.2; = p.G194= on NM_182537.3) | Silent (SNP) | VAF 58/224 reads (26%) | catalogued as COSV100488367; called by muse, mutect2, varscan2
- KRT10 | c.1332T>C p.N444= | Silent (SNP) | VAF 116/202 reads (57%) | catalogued as COSV99510319; called by muse, varscan2
- OBSCN | c.17574G>A p.A5858= | Silent (SNP) | VAF 83/177 reads (47%) | catalogued as rs558801538, COSV52782368; called by muse, mutect2, varscan2
- PRPF3 | c.1921C>A p.R641= | Silent (SNP) | VAF 170/412 reads (41%) | catalogued as COSV100255105; called by muse, mutect2, varscan2
- SNAPC1 | c.66C>T p.D22= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99359430; called by muse, mutect2, varscan2
- SYNE1 | c.25197G>A p.E8399= (on ENST00000367255 / NM_182961.4; = p.E8351= on NM_033071.3) | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV99555215, COSV99579460; called by muse, mutect2, varscan2
- SYNE2 | c.14013G>A p.Q4671= | Silent (SNP) | VAF 54/137 reads (39%) | catalogued as rs1228539994, COSV59967193; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZC3H12A | c.1107A>T p.T369= | Silent (SNP) | VAF 71/149 reads (48%) | catalogued as COSV100897779; called by muse, mutect2, varscan2
- NXNL2 | c.-2C>T | 5'UTR (SNP) | VAF 32/83 reads (39%) | catalogued as COSV101018399; called by muse, mutect2, varscan2
- SSPOP | n.7785C>T | RNA (SNP) | VAF 26/68 reads (38%) | catalogued as rs376985175; called by muse, mutect2, varscan2
